Surgical pathology report (de-identified scan), TCGA case TCGA-IS-A3KA, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IS-A3KA-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Right periaortic lymph nodes (
- 2: SP: Left periaortic lymph nodes (
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left obturator lymph nodes (
- 5: SP: Left hypogastric lymph nodes (
- 6: SP: Left common iliac lymph nodes (
- 7: SP: Right external iliac lymph nodes
- 8: SP: Right obturator lymph nodes (
- 9: SP: Right common iliac lymph nodes (
- 10: SP: Right hypogastric lymph nodes (
- 11: SP: Uterus, bilateral tubes and ovaries (
- 12: SP: Left para-aortic lymph nodes
- 13: SP: Bx of omentum

DIAGNOSIS:

- 1) LYMPH NODES, RIGHT PERIAORTIC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 2) LYMPH NODES, LEFT PERIAORTIC; BIOPSY:
- FOUR BENIGN LYMPH NODES (0/4).
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 4) LYMPH NODES, LEFT OBTURATOR; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODES, LEFT HYPOGASTRIC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 6) LYMPH NODES, LEFT COMMON ILIAC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).
- 7) LYMPH NODES, RIGHT EXTERNAL ILIAC; BIOPSY:

** Continued on next page **

ICD-0-3

leiomyosarcoma, NOS 8890/3

Site: uterus c55.9

fw 12/20/11

[page 2 of 2]
- TWO BENIGN LYMPH NODES (0/2).

8) LYMPH NODES, RIGHT OBTURATOR; BIOPSY:
- EIGHT BENIGN LYMPH NODES (0/8).

9) LYMPH NODES, RIGHT COMMON ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).

10) LYMPH NODES, RIGHT HYPOGASTRIC; BIOPSY:
- BENIGN ADIPOSE TISSUE.

11) UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES; TOTAL ABDOMINAL
HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- HIGH GRADE SARCOMA, MOST CONSISTENT WITH LEIOMYOSARCOMA (SEE NOTE).
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- EXTENSIVE VASCULAR INVASION IS PRESENT.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMA.
- THE LEFT OVARY SHOWS SIMPLE CYST.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.

NOTE: TUMOR CELLS EXPRESS DESMIN, H-CALDESMON, SMA AND FOCAL EMA AND S100.
THEY ARE NEGATIVE FOR MYOGENIN AND AE1/3. REACTIVITY FOR HMB45 IS
EQUIVOCAL. THIS IMMUNOPHENOTYPE SUPPORTS SMOOTH MUSCLE DIFFERENTIATION. OF
INTEREST, THERE IS FOCAL APPARENT LIPOBLASTIC DIFFERENTIATION.

12) LYMPH NODE, LEFT PARA-AORTIC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).

13) OMENTUM; OMENTECTOMY:
- BENIGN ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 57a02806-df5b-4812-9bcd-72a6027bb7ee (TCGA-IS-A3KA.E5939098-DE4B-48DE-935E-1F84EA71BA0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).